Somatic mutation profile of tumor specimen TCGA-AX-A1CN-01A (aliquot TCGA-AX-A1CN-01A-11D-A135-09) from TCGA case TCGA-AX-A1CN, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 54.4 years (19,860 days).
Specimen TCGA-AX-A1CN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ebf6fbd8-f69e-4084-a09c-4ecee9f81543.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A1CN-10A (Blood Derived Normal), aliquot TCGA-AX-A1CN-10A-01D-A135-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e4c770d8-081a-49c4-a1aa-dbdbaeb13d7c

The open-access MAF lists 34 somatic variants for this specimen: 26 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 20, Silent 8, Nonsense Mutation 2, Splice Site 1, Splice Region 1, Translation Start Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 24/55 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: other / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ING1 | c.1015C>T p.R339* | Nonsense Mutation (SNP) | VAF 17/20 reads (85%) | hotspot (GDC flag); catalogued as COSV58167363; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 13/30 reads (43%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.4994-2A>G p.X1665_splice | Splice Site (SNP) | VAF 66/76 reads (87%) | catalogued as COSV100253620, COSV61377871; called by muse, mutect2, varscan2
- ASB16 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99519074; called by muse, mutect2, varscan2
- CR1 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as COSV100888072; called by muse, mutect2, varscan2
- ECE1 | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.35); catalogued as rs779304634, COSV99942379; called by muse, mutect2, varscan2
- EDA2R | c.222C>A p.N74K | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99491023; called by muse, mutect2
- GABRB2 | c.1397G>A p.R466H (on ENST00000274547; = p.R428H on NM_000813.3) | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as rs772293871, COSV50929966; called by muse, mutect2, varscan2
- GPATCH1 | c.150C>G p.H50Q | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99404374; called by muse, mutect2, varscan2
- KDM3B | c.705G>A p.E235= | Splice Region (SNP) | VAF 8/23 reads (35%) | catalogued as COSV100070280; called by muse, mutect2, varscan2
- MAGEC3 | c.1897C>A p.P633T | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as rs919085115, COSV53579520; called by muse, mutect2, varscan2
- MED12 | c.67G>T p.D23Y | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61334558; called by muse, mutect2, varscan2
- MORC3 | c.1726G>A p.D576N | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV68687879; called by muse, mutect2, varscan2
- OR4E2 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100330162; called by muse, mutect2
- PIK3C2A | c.1967T>G p.L656R | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV99791256; called by muse, mutect2, varscan2
- RNF144A | c.482C>G p.P161R | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.358); catalogued as rs765223317, COSV57982983; called by muse, mutect2, varscan2
- RTEL1 | c.1346G>A p.R449Q | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779873020, COSV100542600, COSV100542859; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRGC1 | c.158C>T p.T53M | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as rs563835813; called by muse, mutect2
- TTC21B | c.1333C>T p.P445S | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as rs745883372, COSV99692924; called by muse, mutect2, varscan2
- ZNF407 | c.2527A>T p.R843* | Nonsense Mutation (SNP) | VAF 13/33 reads (39%) | catalogued as COSV99996862; called by muse, mutect2, varscan2
- ZNF532 | c.1516G>A p.V506M | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.078); catalogued as rs370955739, COSV60172026; called by muse, mutect2, varscan2
- ZNF76 | c.989C>T p.S330L | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as rs748775812, COSV57590916; called by muse, mutect2, varscan2
- ZNRD2 | c.277C>G p.L93V | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.151); catalogued as COSV100326226; called by muse, mutect2, varscan2
- STAU1 | c.1266del p.E423Rfs*6 (on ENST00000371856 / NM_001319135.1; = p.E342Rfs*6 on NM_004602.3) | Frame Shift Del (DEL) | VAF 11/45 reads (24%) | called by mutect2, pindel, varscan2
- TRBV5-1 | c.209G>A p.S70N | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BLVRB | c.105G>A p.R35= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV99648073; called by muse, mutect2, varscan2
- CCDC22 | c.1500C>T p.I500= | Silent (SNP) | VAF 21/40 reads (53%) | catalogued as rs1312852817, COSV100873239; called by muse, mutect2, varscan2
- CD6 | c.810C>T p.G270= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as rs768183751, COSV57839091; called by muse, mutect2, varscan2
- LRIT1 | c.42G>A p.A14= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as rs202166415; called by muse, mutect2, varscan2
- PCSK9 | c.966C>T p.A322= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as COSV100135584; called by muse, varscan2
- RREB1 | c.3963G>A p.P1321= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as rs770076990, COSV58558001; called by muse, mutect2, varscan2
- SPARC | c.639G>A p.V213= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV99163888; called by muse, mutect2, varscan2
- STRN3 | c.1800A>G p.Q600= (on ENST00000357479 / NM_001083893.2; = p.Q516= on NM_014574.4) | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs1190803321, COSV100671077; called by muse, mutect2, varscan2
